Somatic mutation profile of tumor specimen TCGA-C5-A1BL-01A (aliquot TCGA-C5-A1BL-01A-11D-A13W-08) from TCGA case TCGA-C5-A1BL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 32.1 years (11,723 days).
Specimen TCGA-C5-A1BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2240adf4-2525-4445-beba-7b6f665ec21a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1BL-10A (Blood Derived Normal), aliquot TCGA-C5-A1BL-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33d7a056-eb0e-4f7d-aba7-81cb123acbac

The open-access MAF lists 239 somatic variants for this specimen: 174 protein-altering or splice-affecting, 62 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 62, Nonsense Mutation 18, Splice Site 3, RNA 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.3450T>G p.Y1150* (on ENST00000272895 / NM_173076.3; = p.Y832* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as COSV55949577; called by muse, mutect2, varscan2
- ABCA6 | c.75G>C p.R25S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99447371; called by muse, mutect2
- ACE | c.1116C>T p.F372= | Splice Region (SNP) | VAF 70/100 reads (70%) | catalogued as COSV52003537; called by muse, mutect2, varscan2
- ADGRE5 | c.1810G>A p.E604K (on ENST00000242786 / NM_078481.4; = p.E511K on NM_001784.5) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV54390455; called by muse, mutect2, varscan2
- ADH1B | c.494C>A p.S165* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV59295103; called by muse, mutect2, varscan2
- AMMECR1L | c.473C>G p.S158* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV55760016; called by muse, mutect2, varscan2
- AMPD1 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV100815174; called by muse, mutect2
- ANO3 | c.2868G>A p.M956I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.833); catalogued as COSV56780674, COSV56781088; called by muse, mutect2, varscan2
- APAF1 | c.1096G>A p.E366K (on ENST00000551964 / NM_181861.2; = p.E355K on NM_001160.3) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100244342; called by muse, mutect2, varscan2
- APBB1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781050131, COSV54972874; called by muse, mutect2, varscan2
- APH1A | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52528259, COSV52528319; called by muse, mutect2, varscan2
- ARFGEF2 | c.3508G>C p.E1170Q | Missense Mutation (SNP) | VAF 30/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904400, COSV64211476; called by muse, mutect2
- ARHGEF19 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.319); catalogued as COSV54615102; called by muse, mutect2, varscan2
- ATRN | c.3484G>C p.D1162H | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53529881, COSV99497657; called by muse, mutect2
- B3GNT6 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV62829466; called by muse, mutect2
- BPIFB4 | c.884G>C p.C295S | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64950692, COSV64951981; called by muse, mutect2, varscan2
- C1orf131 | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 15/264 reads (6%) | catalogued as COSV100009959; called by muse, mutect2
- CACNB4 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as rs1553740187, COSV52389169; called by muse, mutect2, varscan2
- CALCOCO1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV50411796; called by muse, mutect2, varscan2
- CCDC120 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as rs974624326, COSV64480590; called by muse, mutect2, varscan2
- CCDC14 | c.1900C>T p.H634Y (on ENST00000488653; = p.H586Y on NM_022757.5) | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs953430141, COSV59942931; called by muse, mutect2, varscan2
- CDH22 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.247); catalogued as COSV64836519; called by muse, mutect2
- CDH23 | c.4582G>A p.E1528K | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.157); catalogued as rs201533282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDIN1 | c.664G>A p.E222K (on ENST00000437989; = p.E124K on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.599); catalogued as COSV57709799; called by muse, mutect2, varscan2
- CDR1 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV65163851; called by muse, mutect2, varscan2
- CELSR2 | c.5599G>C p.E1867Q | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.571); catalogued as COSV54771640; called by muse, mutect2
- CFAP54 | c.6289C>G p.Q2097E | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.58); catalogued as COSV61570698; called by muse, varscan2
- CHRDL1 | c.391C>T p.R131W (on ENST00000372045; = p.R137W on NM_145234.4) | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749956744, COSV54324410; called by muse, mutect2
- CHST3 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as COSV64150434; called by muse, mutect2, varscan2
- CLMN | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54179081; called by muse, mutect2, varscan2
- COASY | c.61C>G p.R21G | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV55897548; called by muse, mutect2, varscan2
- CPAMD8 | c.3998C>T p.S1333L (on ENST00000651564; = p.S1286L on NM_015692.5) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV101488557; called by muse, mutect2
- CR1 | c.5159A>G p.H1720R | Missense Mutation (SNP) | VAF 68/572 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV65456000; called by muse, mutect2, varscan2
- CRB1 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV66336533; called by muse, mutect2, varscan2
- CSDE1 | c.1751C>G p.S584* (on ENST00000358528 / NM_001007553.3; = p.S553* on NM_007158.6) | Nonsense Mutation (SNP) | VAF 15/227 reads (7%) | catalogued as COSV99795688; called by muse, mutect2
- CSMD3 | c.10288C>G p.H3430D (on ENST00000297405 / NM_001363185.1; = p.H3261D on NM_052900.3) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV52106150; called by muse, mutect2, varscan2
- CTNNAL1 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); catalogued as rs774871628, COSV57701395, COSV57705126; called by muse, mutect2, varscan2
- CUBN | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.061); catalogued as COSV64708155, COSV64712888; called by muse, mutect2, varscan2
- DHCR24 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV64874208; called by muse, varscan2
- DNAH2 | c.6994G>T p.E2332* | Nonsense Mutation (SNP) | VAF 52/165 reads (32%) | catalogued as COSV66716528; called by muse, mutect2, varscan2
- DOCK10 | c.4542G>C p.L1514F | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV51348723; called by muse, mutect2, varscan2
- DOCK8 | c.1687C>G p.L563V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV66617700; called by muse, mutect2, varscan2
- DSP | c.4672C>T p.R1558W | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs777102300, COSV65791236; called by muse, mutect2, varscan2
- DST | c.1945G>C p.E649Q (on ENST00000361203 / NM_001374722.1; = p.E323Q on NM_001723.6) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54998461; called by muse, mutect2, varscan2
- DYNC1H1 | c.9897C>G p.I3299M | Missense Mutation (SNP) | VAF 34/632 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795221; called by muse, mutect2
- ENAM | c.2367G>C p.Q789H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV68535238; called by muse, mutect2, varscan2
- EPAS1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV99763449; called by muse, mutect2
- EXOSC4 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60155300; called by muse, mutect2, varscan2
- FAM47C | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.034); catalogued as rs782236901, COSV100792871; called by muse, mutect2
- FANCL | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52072709; called by muse, mutect2, varscan2
- FAT4 | c.13426C>G p.P4476A | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.991); catalogued as rs1369740422, COSV58672131; called by muse, mutect2, varscan2
- FBXO43 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV101413901; called by muse, mutect2
- FCRL1 | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.213); catalogued as COSV63823860; called by muse, mutect2, varscan2
- FCRL1 | c.31+2T>C p.X11_splice | Splice Site (SNP) | VAF 11/74 reads (15%) | catalogued as COSV63823865; called by muse, mutect2, varscan2
- FKBP8 | c.1102C>A p.L368M (on ENST00000222308 / NM_001308373.2; = p.L369M on NM_012181.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV55891125; called by muse, mutect2, varscan2
- GGH | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52649300, COSV52650907; called by muse, mutect2, varscan2
- GPR137B | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV63990707; called by muse, mutect2, varscan2
- GPR156 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV59938111; called by muse, mutect2, varscan2
- GPR176 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV54443497; called by muse, mutect2, varscan2
- GPR85 | c.861C>G p.F287L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV51783159, COSV99775258; called by muse, mutect2
- H1-4 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs766257287, COSV99175334; called by muse, mutect2, varscan2
- H2BC12 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100804565, COSV63616725; called by muse, mutect2
- H2BC21 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 28/381 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2
- HTR1F | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV60389006; called by muse, mutect2, varscan2
- HTT | c.2509C>G p.L837V | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV61857582; called by muse, mutect2, varscan2
- IFNGR1 | c.917C>G p.S306* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV62989414, COSV62990148, COSV62990505; called by muse, mutect2, varscan2
- IQSEC2 | c.1465G>A p.E489K (on ENST00000642864 / NM_001111125.3; = p.E284K on NM_015075.2) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV100945041; called by muse, mutect2
- KIF12 | c.1862G>A p.R621K (on ENST00000640217; = p.R483K on NM_138424.1) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.297); catalogued as COSV65116656; called by muse, mutect2
- KIF21B | c.3127G>C p.D1043H | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.564); catalogued as COSV100144944; called by muse, mutect2
- KIF26B | c.3859G>A p.A1287T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV63636922; called by muse, mutect2, varscan2
- KIFC2 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs1404760390, COSV56759965; called by muse, mutect2, varscan2
- KMT2C | c.13861G>T p.E4621* | Nonsense Mutation (SNP) | VAF 42/61 reads (69%) | catalogued as COSV51298459; called by muse, mutect2, varscan2
- KRT17 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs753353264, COSV60859971; called by muse, mutect2
- KRT84 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 89/324 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs146876431; called by muse, mutect2, varscan2
- LEFTY2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs375598455; called by muse, mutect2, varscan2
- LEPR | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV60747550; called by muse, mutect2, varscan2
- LIMA1 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as COSV57963962; called by muse, mutect2, varscan2
- LRIG2 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV63160855; called by muse, mutect2, varscan2
- MAP4K3 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99810889; called by muse, mutect2
- MCRS1 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV59458414; called by muse, mutect2
- MCRS1 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59458427; called by muse, mutect2, varscan2
- MED12L | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV56368884; called by muse, varscan2
- MGAM | c.4679T>C p.F1560S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV72073672; called by muse, mutect2, varscan2
- MIA3 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.261); catalogued as rs1198713688, COSV60510027; called by muse, mutect2, varscan2
- MKLN1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV61760005; called by muse, mutect2, varscan2
- MPZL1 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV63256004; called by muse, mutect2, varscan2
- MTMR1 | c.1940C>A p.S647* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as COSV60934968; called by mutect2, varscan2
- MUC16 | c.13729G>A p.A4577T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs372775227; called by muse, mutect2, varscan2
- MUC17 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 134/670 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60280441; called by muse, mutect2, varscan2
- MXRA5 | c.7276G>A p.E2426K | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs779746828, COSV54224284; called by muse, mutect2, varscan2
- MYO1H | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1207034312, COSV60443123; called by muse, mutect2, varscan2
- MYO9A | c.7072G>A p.E2358K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100614057; called by mutect2, varscan2
- MYO9B | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68277064; called by muse, mutect2, varscan2
- NAA16 | c.1488G>T p.Q496H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); catalogued as COSV65064204; called by mutect2, varscan2
- NEK8 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52042951; called by muse, mutect2, varscan2
- NFE2L2 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV67960188, COSV67961032; called by muse, mutect2, varscan2
- NFE2L2 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV67960190; called by muse, mutect2, varscan2
- NRP1 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV104375226, COSV99589276; called by muse, mutect2
- OR2A12 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs777960925, COSV68821052; called by muse, mutect2, varscan2
- OR4C12 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as rs868956125, COSV58859434, COSV58859793; called by muse, mutect2, varscan2
- OR4M1 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV60059555; called by muse, mutect2, varscan2
- OR5H6 | c.752G>A p.R251Q (on ENST00000642105; = p.R235Q on NM_001005479.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.248); catalogued as rs145676438; called by muse, mutect2, varscan2
- PAN3 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56701176; called by muse, mutect2, varscan2
- PARP1 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64687764, COSV64687927; called by muse, mutect2, varscan2
- PCLO | c.3678G>C p.K1226N | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100433351, COSV61616820; called by muse, mutect2, varscan2
- PDK4 | c.772-1G>A p.X258_splice | Splice Site (SNP) | VAF 6/79 reads (8%) | catalogued as COSV99138919; called by muse, mutect2
- PELI3 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57856064; called by muse, mutect2, varscan2
- PHRF1 | c.4717G>A p.E1573K (on ENST00000264555 / NM_001286581.2; = p.E1572K on NM_020901.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52751205; called by muse, mutect2
- PIGA | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); catalogued as COSV100363498; called by muse, mutect2
- PITX2 | c.185-1G>A p.X62_splice (on ENST00000354925 / NM_001204397.1; = p.X69_splice on NM_000325.6) | Splice Site (SNP) | VAF 14/98 reads (14%) | catalogued as CS004085, CS044764, COSV60740236; called by muse, mutect2, varscan2
- PIWIL1 | c.2561T>C p.L854P | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55344217; called by muse, mutect2, varscan2
- PKD2L2 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV51799335; called by muse, mutect2
- PLPBP | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV60239340; called by muse, mutect2, varscan2
- PLXNA1 | c.3679G>T p.E1227* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV52522388; called by muse, mutect2
- PRKDC | c.10705C>G p.Q3569E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58043306; called by muse, mutect2, varscan2
- PRKDC | c.4833G>C p.Q1611H | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV58043326; called by muse, mutect2, varscan2
- PSKH2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV99405286; called by muse, mutect2, varscan2
- PTPRG | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55629174; called by muse, mutect2, varscan2
- RAD23B | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV63657684; called by muse, mutect2, varscan2
- RAPGEF2 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV52424885; called by muse, mutect2, varscan2
- RDH5 | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.791); catalogued as COSV99141853, COSV99141889; called by muse, mutect2
- RELN | c.8564G>A p.G2855E | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV58986480; called by muse, mutect2, varscan2
- RRN3 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 33/134 reads (25%) | catalogued as COSV52213242; called by muse, mutect2, varscan2
- RRP9 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs147742914; called by muse, mutect2, varscan2
- RYR2 | c.4793G>A p.R1598K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1056392680, COSV63663260, COSV63678077; called by muse, mutect2, varscan2
- SEPTIN6 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 40/492 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV100595719; called by muse, mutect2
- SERPINI1 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | catalogued as COSV55508060, COSV99855064; called by muse, mutect2, varscan2
- SIPA1L2 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.3); catalogued as COSV53383766; called by muse, mutect2, varscan2
- SLC25A21 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV100491167, COSV58715057; called by muse, mutect2, varscan2
- SLITRK1 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.199); catalogued as rs778746061, COSV65674314, COSV65675546; called by muse, varscan2
- SORBS1 | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53353347; called by muse, mutect2, varscan2
- SPATA31D1 | c.2574G>T p.K858N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs758284801, COSV61192873, COSV61194351; called by muse, mutect2, varscan2
- SPEN | c.3326C>G p.S1109* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV101005506; called by muse, mutect2
- STAB2 | c.3659G>A p.R1220H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151309446; called by muse, mutect2, varscan2
- SUMF1 | c.734C>G p.P245R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55991763; called by muse, mutect2
- SVEP1 | c.4682G>T p.G1561V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990863; called by muse, mutect2
- SYK | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs139388374; called by muse, mutect2, varscan2
- TAF6 | c.760C>G p.Q254E | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.085); catalogued as COSV59840641; called by muse, mutect2, varscan2
- TAOK2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99665195; called by muse, mutect2
- TCF20 | c.3048G>C p.L1016F | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV59488503; called by muse, mutect2, varscan2
- TEAD1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57561501; called by muse, mutect2, varscan2
- TEX15 | c.7087C>G p.H2363D (on ENST00000256246; = p.H2746D on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.813); catalogued as COSV56341763; called by muse, mutect2, varscan2
- THBS3 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as rs1302366318, COSV100857681; called by muse, mutect2
- THRAP3 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs780723624, COSV63566679; called by muse, mutect2, varscan2
- TM2D3 | c.334G>C p.D112H (on ENST00000333202 / NM_078474.3; = p.D86H on NM_025141.3) | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as COSV60880675; called by muse, mutect2, varscan2
- TMEM168 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57179391; called by muse, mutect2, varscan2
- TNC | c.2689A>G p.R897G | Missense Mutation (SNP) | VAF 83/417 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV60780628; called by muse, mutect2, varscan2
- TRIM56 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV60157234; called by muse, mutect2, varscan2
- TRIML1 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as COSV60193346; called by muse, mutect2, varscan2
- TSPOAP1 | c.5536G>A p.E1846K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52104169, COSV99270070; called by muse, mutect2
- TTN | c.72202G>A p.D24068N (on ENST00000591111; = p.D16644N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | PolyPhen probably damaging (0.996); catalogued as COSV59895434, COSV60033636; called by muse, mutect2, varscan2
- TTN | c.22315G>A p.D7439N (on ENST00000591111; = p.D6512N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | PolyPhen benign (0); catalogued as COSV59895474; called by muse, mutect2, varscan2
- TTN | c.5524G>A p.D1842N (on ENST00000591111; = p.D1796N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | PolyPhen possibly damaging (0.691); catalogued as rs1469586209, COSV59895489; called by muse, mutect2, varscan2
- TUB | c.1078A>T p.S360C (on ENST00000299506 / NM_177972.3; = p.S415C on NM_003320.4) | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55106628; called by muse, mutect2, varscan2
- UACA | c.3134G>C p.R1045T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as COSV59853358; called by muse, mutect2, varscan2
- UBR4 | c.7357C>G p.L2453V | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100921438; called by muse, mutect2
- UNC79 | c.5434G>A p.E1812K (on ENST00000393151 / NM_001346218.2; = p.E1635K on NM_020818.5) | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99829302; called by muse, mutect2
- UNCX | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100310303, COSV60332803, COSV60332865; called by muse, mutect2, varscan2
- USP48 | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs748095023, COSV57607298; called by muse, mutect2, varscan2
- VWA3A | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 71/371 reads (19%) | catalogued as COSV55388054; called by muse, mutect2, varscan2
- WDFY3 | c.1925G>C p.R642T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55693663, COSV55694574; called by muse, mutect2
- WDR55 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100845594, COSV64225654; called by muse, mutect2
- WWP2 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as rs1315198496, COSV63123169, COSV63125518; called by muse, mutect2, varscan2
- ZBTB12 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs555290175, COSV64993558; called by muse, varscan2
- ZNF227 | c.1682C>G p.S561* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV57311289; called by muse, mutect2, varscan2
- ZNF236 | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53482616; called by muse, mutect2, varscan2
- ZNF559 | c.1386G>C p.E462D | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as COSV57834976; called by muse, mutect2, varscan2
- ZNF676 | c.1733C>T p.S578L (on ENST00000650058; = p.S546L on NM_001001411.3) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1320229354, COSV68092216; called by muse, mutect2, varscan2
- ZNF681 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs751235649, COSV68074210; called by muse, mutect2
- ZNF91 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs1189964950, COSV56094189; called by muse, mutect2
- CELSR2 | c.5349G>C p.E1783D | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.199); called by muse, mutect2
- CHRNB3 | c.930_933del p.I311Lfs*38 | Frame Shift Del (DEL) | VAF 62/361 reads (17%) | called by mutect2, pindel, varscan2
- DLG2 | c.692_694del p.G231del | In Frame Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- TRAF6 | c.980dup p.S328Kfs*2 | Frame Shift Ins (INS) | VAF 73/232 reads (31%) | called by mutect2, pindel, varscan2
- ABCC12 | c.3270C>G p.L1090= | Silent (SNP) | VAF 62/313 reads (20%) | catalogued as COSV60911653; called by muse, mutect2, varscan2
- ABCC12 | c.3138G>A p.L1046= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as COSV60911658; called by muse, mutect2, varscan2
- ACRBP | c.1068C>T p.F356= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs912506881, COSV57523105; called by muse, mutect2, varscan2
- ACTL6A | c.627C>T p.L209= | Silent (SNP) | VAF 35/313 reads (11%) | catalogued as COSV66998637; called by muse, mutect2, varscan2
- AGPAT1 | c.851G>A p.*284= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV61247047; called by muse, mutect2, varscan2
- ALG3 | c.393C>A p.L131= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as COSV99891578; called by muse, mutect2
- ARSD | c.648C>T p.A216= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs113318393, COSV54198912; called by muse, mutect2
- BCAR3 | c.1545C>T p.F515= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as COSV53072089; called by muse, mutect2, varscan2
- CDH11 | c.1842C>A p.G614= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV51751613; called by muse, mutect2, varscan2
- CELF4 | c.462C>T p.L154= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs1266456566, COSV58446946; called by muse, mutect2, varscan2
- CLCC1 | c.1536G>A p.A512= (on ENST00000356970 / NM_001377464.1; = p.A462= on NM_015127.5) | Silent (SNP) | VAF 32/180 reads (18%) | catalogued as rs772609730, COSV51444793; called by muse, varscan2
- CNOT1 | c.345G>C p.L115= | Silent (SNP) | VAF 15/207 reads (7%) | catalogued as rs1354081239, COSV100409811; called by muse, mutect2
- COL4A1 | c.1560G>A p.L520= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs767901841, COSV65421540; called by muse, mutect2, varscan2
- CREBBP | c.1902G>A p.K634= | Silent (SNP) | VAF 64/194 reads (33%) | catalogued as rs1323027664, COSV99271206; called by muse, mutect2, varscan2
- CSAD | c.156G>C p.L52= (on ENST00000444623 / NM_001244705.2; = p.L79= on NM_015989.5) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99914931; called by muse, mutect2, varscan2
- EGFR | c.519C>G p.L173= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV51772702; called by muse, mutect2, varscan2
- ELMO1 | c.303G>A p.L101= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV60295738; called by muse, mutect2, varscan2
- FAT1 | c.7737C>T p.F2579= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV71672034, COSV71676643; called by muse, mutect2, varscan2
- FBXW12 | c.1098C>T p.F366= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV56482907; called by muse, mutect2, varscan2
- FZD4 | c.237G>C p.L79= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV72294207; called by muse, varscan2
- GALC | c.687C>G p.L229= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99730266; called by muse, mutect2, varscan2
- IMMP2L | c.339C>T p.V113= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV59219342; called by muse, mutect2, varscan2
- ITGA7 | c.498C>T p.L166= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV57691821; called by muse, mutect2, varscan2
- KCNAB1 | c.600G>A p.Q200= (on ENST00000490337 / NM_172160.3; = p.Q189= on NM_003471.3) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV56741456; called by muse, mutect2, varscan2
- KLHL15 | c.567G>A p.L189= | Silent (SNP) | VAF 84/439 reads (19%) | catalogued as COSV60139195; called by muse, mutect2, varscan2
- LILRB2 | c.1170C>T p.H390= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as rs373595683; called by muse, varscan2
- MBLAC1 | c.618G>C p.L206= | Silent (SNP) | VAF 3/52 reads (6%) | catalogued as COSV99498886; called by muse, mutect2
- MROH9 | c.1599G>A p.V533= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV63010039; called by muse, mutect2, varscan2
- MUC16 | c.28134G>A p.S9378= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs768725604, COSV67445960; called by muse, mutect2, varscan2
- MYOM3 | c.1653G>A p.S551= | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as rs376623497; called by muse, mutect2, varscan2
- NCOA2 | c.33C>T p.P11= | Silent (SNP) | VAF 44/195 reads (23%) | catalogued as rs1465537512, COSV71763466; called by muse, mutect2, varscan2
- NFKBIA | c.291G>A p.V97= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV53751604, COSV53752460; called by muse, mutect2, varscan2
- NLRP12 | c.222C>G p.L74= | Silent (SNP) | VAF 46/240 reads (19%) | catalogued as COSV60743764; called by muse, mutect2, varscan2
- NRK | c.1416G>C p.R472= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54590120, COSV54597109; called by muse, mutect2, varscan2
- PALLD | c.732G>A p.Q244= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV54973238; called by muse, mutect2, varscan2
- PCDH18 | c.63C>T p.F21= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV61266473; called by muse, mutect2, varscan2
- PCDHA13 | c.1824G>A p.S608= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs1443036011, COSV56474765; called by muse, mutect2, varscan2
- PCDHGA5 | c.666C>G p.L222= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as COSV53901444; called by muse, mutect2, varscan2
- PCDHGA6 | c.1848T>C p.L616= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs746995876, COSV99543883; called by muse, mutect2, varscan2
- PURG | c.393G>C p.L131= | Silent (SNP) | VAF 37/211 reads (18%) | catalogued as COSV53295591, COSV53296220; called by muse, mutect2, varscan2
- QSOX1 | c.1593C>T p.L531= | Silent (SNP) | VAF 20/427 reads (5%) | catalogued as rs768556738, COSV100852969, COSV62580518; called by muse, mutect2
- RBL1 | c.1578C>G p.L526= | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV60329527, COSV60331968; called by muse, mutect2
- RILP | c.774C>G p.L258= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV53957429; called by muse, mutect2, varscan2
- SEC14L3 | c.627G>C p.L209= | Silent (SNP) | VAF 53/236 reads (22%) | catalogued as COSV99307280; called by muse, mutect2, varscan2
- SERPINH1 | c.438C>T p.F146= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs1367682527, COSV63997665; called by muse, mutect2, varscan2
- SLC17A8 | c.546C>T p.Y182= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs778435501, COSV60121921; called by muse, mutect2, varscan2
- SOCS6 | c.837C>T p.I279= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as COSV67545974; called by muse, mutect2, varscan2
- SPTA1 | c.1638C>T p.D546= | Silent (SNP) | VAF 64/137 reads (47%) | catalogued as rs760642196, COSV63749160; called by muse, mutect2, varscan2
- STX11 | c.612C>T p.L204= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV62448481; called by mutect2, varscan2
- SUFU | c.1149C>G p.L383= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV64013926; called by muse, mutect2, varscan2
- TDRD5 | c.228G>A p.L76= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs144528038; called by muse, mutect2, varscan2
- TDRD6 | c.1188G>A p.L396= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV100288091; called by muse, mutect2
- TRIML1 | c.1227C>T p.V409= | Silent (SNP) | VAF 90/300 reads (30%) | catalogued as COSV60193356; called by muse, varscan2
- TTC27 | c.738G>A p.E246= | Silent (SNP) | VAF 42/169 reads (25%) | catalogued as COSV58648932; called by muse, mutect2, varscan2
- TUBB | c.987G>A p.Q329= | Silent (SNP) | VAF 59/183 reads (32%) | catalogued as COSV58357291, COSV58357578; called by muse, mutect2, varscan2
- USHBP1 | c.1477C>T p.L493= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- UTP14A | c.84G>A p.L28= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV64100966, COSV64101995; called by muse, mutect2, varscan2
- VASN | c.1311G>A p.T437= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs369159357; called by muse, mutect2
- WASHC4 | c.3414G>A p.K1138= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV59888512; called by muse, mutect2, varscan2
- ZNF184 | c.1969C>T p.L657= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs749865285, COSV53003191; called by muse, mutect2, varscan2
- ZNF25 | c.315C>G p.L105= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV56921747; called by muse, mutect2, varscan2
- ZNF615 | c.1665C>G p.L555= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as COSV65032080; called by muse, mutect2, varscan2
- HROB | c.*1G>C | 3'UTR (SNP) | VAF 35/169 reads (21%) | catalogued as COSV99809338; called by muse, mutect2, varscan2
- LINC02877 | n.307C>T | RNA (SNP) | VAF 51/409 reads (12%) | called by muse, mutect2, varscan2
- VPS26C | chr21:37221373 G>A | 3'Flank (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
